Somatic mutation profile of tumor specimen TCGA-GD-A3OS-01A (aliquot TCGA-GD-A3OS-01A-12D-A21Z-08) from TCGA case TCGA-GD-A3OS, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 54.1 years (19,776 days).
Specimen TCGA-GD-A3OS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5aea20ea-1535-4cec-9a78-224eaa337bf3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GD-A3OS-10A (Blood Derived Normal), aliquot TCGA-GD-A3OS-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad7ac878-c23c-46ee-88ab-db60175ab9b1

The open-access MAF lists 106 somatic variants for this specimen: 77 protein-altering or splice-affecting, 24 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 24, Nonsense Mutation 4, Intron 3, Frame Shift Del 3, Frame Shift Ins 2, Splice Site 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 14/17 reads (82%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 59/80 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS5 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.985); catalogued as rs757921094, COSV53179079; called by muse, mutect2, varscan2
- ANAPC1 | c.4984C>A p.L1662I | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as COSV61975239; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1529T>C p.I510T | Missense Mutation (SNP) | VAF 199/315 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772784086, COSV50055912; called by muse, mutect2, varscan2
- CDH16 | c.608T>C p.L203P | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.776); catalogued as COSV55336595; called by muse, mutect2, varscan2
- CEP63 | c.1888A>G p.N630D | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV59676333; called by muse, mutect2, varscan2
- CFHR2 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.056); catalogued as rs777460690, COSV66381100; called by muse, mutect2, varscan2
- CHML | c.210A>C p.E70D | Missense Mutation (SNP) | VAF 68/290 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV59364226; called by muse, mutect2, varscan2
- CNTNAP2 | c.2807G>A p.C936Y | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62180988; called by muse, mutect2, varscan2
- COMT | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52889652; called by muse, mutect2, varscan2
- CPSF6 | c.698G>C p.G233A | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as COSV57014558; called by muse, mutect2, varscan2
- CSF1R | c.1213A>C p.S405R | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV53834832; called by muse, mutect2, varscan2
- CYB5R3 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs1226180422, COSV61545255; called by muse, mutect2, varscan2
- DACT1 | c.1732G>A p.V578I | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1426512895, COSV60019271; called by muse, mutect2, varscan2
- ECI2 | c.98G>A p.R33K (on ENST00000380118 / NM_206836.3; = p.R3K on NM_006117.2) | Missense Mutation (SNP) | VAF 57/96 reads (59%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV60986418; called by muse, mutect2, varscan2
- ELFN2 | c.1937A>T p.D646V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV68744573; called by muse, mutect2, varscan2
- EXOC4 | c.1459T>C p.F487L | Missense Mutation (SNP) | VAF 123/201 reads (61%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as COSV54098187; called by muse, mutect2, varscan2
- FAM170A | c.234C>A p.D78E | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV58925148; called by muse, mutect2, varscan2
- FMN1 | c.4103G>A p.R1368Q (on ENST00000616417 / NM_001277313.2; = p.R1145Q on NM_001103184.4) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs375921747; called by muse, mutect2, varscan2
- GLYCTK | c.1310G>T p.W437L | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV59793668; called by muse, mutect2, varscan2
- GNG4 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 98/177 reads (55%) | SIFT tolerated (0.61); PolyPhen benign (0.129); catalogued as COSV63999406; called by muse, mutect2, varscan2
- GPC5 | c.689A>T p.N230I | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV65598809, COSV65615819; called by muse, mutect2, varscan2
- GRAMD1C | c.830A>C p.K277T | Missense Mutation (SNP) | VAF 84/106 reads (79%) | SIFT tolerated (0.18); PolyPhen benign (0.425); catalogued as COSV63982742; called by muse, mutect2, varscan2
- HSPA14 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV65684346; called by muse, mutect2, varscan2
- KCTD2 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as COSV100483197; called by muse, mutect2, varscan2
- KIF21A | c.2391G>T p.Q797H (on ENST00000361418 / NM_001378440.1; = p.Q784H on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/174 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV62771443; called by muse, mutect2, varscan2
- KIFAP3 | c.2177G>A p.G726E | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as COSV63033769; called by muse, mutect2, varscan2
- MAP1B | c.3289G>A p.E1097K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs774101263, COSV57098980; called by muse, mutect2, varscan2
- MARCO | c.1472C>T p.T491M | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs772912755, COSV59054371; called by muse, mutect2, varscan2
- MTMR3 | c.2012G>A p.R671K | Missense Mutation (SNP) | VAF 59/102 reads (58%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV60304321, COSV60308565; called by muse, mutect2, varscan2
- MYCN | c.134dup p.E47Gfs*8 | Frame Shift Ins (INS) | VAF 7/40 reads (18%) | catalogued as rs780080562; called by mutect2, varscan2
- NLRP9 | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV60460162, COSV60463028; called by muse, mutect2, varscan2
- NMBR | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376623534; called by muse, mutect2, varscan2
- OGA | c.1075T>A p.L359I | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV63381683; called by muse, mutect2, varscan2
- OGG1 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs541588028, COSV56538747; called by muse, mutect2, varscan2
- OR4C46 | c.779C>A p.A260E | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.281); catalogued as rs749744998, COSV60219361, COSV60219607; called by muse, mutect2, varscan2
- OR5K1 | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.861); catalogued as COSV60304000; called by muse, mutect2, varscan2
- OSCP1 | c.985G>C p.E329Q (on ENST00000356637 / NM_001330493.1; = p.E319Q on NM_145047.5) | Missense Mutation (SNP) | VAF 59/283 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV52486095; called by muse, mutect2, varscan2
- PACC1 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs141387916; called by muse, mutect2, varscan2
- PARP10 | c.1778-1G>A p.X593_splice | Splice Site (SNP) | VAF 10/51 reads (20%) | catalogued as COSV57297803; called by muse, mutect2, varscan2
- PCDH17 | c.997G>T p.A333S | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.595); catalogued as COSV64974129; called by muse, mutect2, varscan2
- PCDH7 | c.2968C>T p.P990S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62338871; called by muse, mutect2, varscan2
- PCDHGB3 | c.649G>T p.G217W | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53947247, COSV99541757; called by muse, mutect2, varscan2
- PCSK2 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs923748750, COSV52731452, COSV99360187; called by muse, mutect2, varscan2
- PIK3C3 | c.1041G>T p.Q347H | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV56279346; called by muse, mutect2, varscan2
- PLCB3 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.459); catalogued as COSV54188507; called by muse, mutect2, varscan2
- PPARG | c.1480C>T p.H494Y (on ENST00000287820 / NM_015869.5; = p.H464Y on NM_005037.7) | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV55142387; called by muse, mutect2, varscan2
- PRAM1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.737); catalogued as rs768282181, COSV55313716; called by muse, mutect2, varscan2
- PRKG2 | c.1595C>A p.A532D | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52324076; called by muse, mutect2, varscan2
- PRSS36 | c.2453C>T p.S818F | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV51637305; called by muse, mutect2, varscan2
- RAPGEF6 | c.1379A>G p.K460R | Missense Mutation (SNP) | VAF 75/101 reads (74%) | SIFT tolerated (0.14); PolyPhen benign (0.291); catalogued as COSV57246491; called by muse, mutect2, varscan2
- RPRD2 | c.3508C>T p.R1170W | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as rs1365856168, COSV64820240; called by muse, mutect2, varscan2
- SLC25A40 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 128/242 reads (53%) | SIFT tolerated (0.54); PolyPhen benign (0.085); catalogued as COSV62019912; called by muse, mutect2, varscan2
- SLCO1C1 | c.395T>C p.F132S | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56872575; called by muse, mutect2, varscan2
- SORBS3 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1563815131, COSV53552939; called by muse, mutect2, varscan2
- SPTA1 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63753042; called by muse, mutect2, varscan2
- SSH1 | c.1040_1041del p.N347Ifs*10 | Frame Shift Del (DEL) | VAF 29/125 reads (23%) | catalogued as COSV58456458; called by mutect2, pindel, varscan2
- ST6GALNAC3 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 57/118 reads (48%) | PolyPhen benign (0.003); catalogued as COSV60332092; called by muse, mutect2, varscan2
- STK3 | c.1435G>C p.D479H | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV69223487; called by muse, mutect2, varscan2
- TAGLN3 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 64/316 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV56327918; called by muse, mutect2, varscan2
- TRIM58 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.15); catalogued as COSV63570217; called by muse, mutect2, varscan2
- TUT7 | c.2914G>T p.G972C | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1228233994, COSV52895693; called by muse, mutect2, varscan2
- ZBTB40 | c.2320A>T p.T774S | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV65145300; called by muse, mutect2, varscan2
- ZDBF2 | c.464T>C p.I155T | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV65625954; called by muse, mutect2, varscan2
- ZFHX4 | c.7795G>A p.G2599S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as rs373737718, COSV99268201; called by muse, mutect2, varscan2
- ZNF431 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.175); catalogued as rs181764553, COSV60671994, COSV60673036; called by muse, mutect2, varscan2
- ZNF528 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 45/323 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64619385, COSV64620446; called by muse, mutect2, varscan2
- ZNF607 | c.1478C>G p.T493S | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV67696877; called by muse, mutect2, varscan2
- ZNF71 | c.1078G>A p.G360S | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV60147238; called by muse, mutect2, varscan2
- ZNF780A | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 49/236 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.096); catalogued as COSV61815420; called by muse, mutect2, varscan2
- CARMIL1 | c.2459dup p.N820Kfs*10 | Frame Shift Ins (INS) | VAF 32/126 reads (25%) | called by mutect2, pindel, varscan2
- ETS2 | c.930_942del p.F311Kfs*98 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel
- EXT2 | c.924C>G p.Y308* (on ENST00000343631; = p.Y341* on NM_000401.3) | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- MYBPH | c.1078_1084del p.H360Rfs*55 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | called by mutect2, pindel
- PARP15 | c.1848C>A p.Y616* (on ENST00000464300 / NM_001113523.3; = p.Y382* on NM_152615.2) | Nonsense Mutation (SNP) | VAF 19/94 reads (20%) | called by muse, mutect2, varscan2
- UPK3B | c.362C>T p.A121V (on ENST00000257632; = p.A66V on NM_001347684.2) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AKAP6 | c.4356C>T p.D1452= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as COSV55213880; called by muse, mutect2, varscan2
- BIRC6 | c.2577C>G p.L859= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV70199244; called by muse, mutect2, varscan2
- CAMK4 | c.564C>G p.L188= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs763176651, COSV56670853; called by muse, mutect2, varscan2
- CLIC5 | c.741C>A p.I247= (on ENST00000185206 / NM_001370649.1; = p.I88= on NM_016929.5) | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as rs1452376505, COSV51758791; called by muse, mutect2, varscan2
- CRAMP1 | c.1272G>T p.V424= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as COSV51962133; called by muse, mutect2, varscan2
- DAPK1 | c.1320G>T p.V440= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV63787386; called by muse, mutect2, varscan2
- DDX55 | c.1434C>T p.D478= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as rs1380899547, COSV53016113; called by muse, mutect2, varscan2
- DPH5 | c.12C>T p.L4= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs1292534097, COSV59859523; called by muse, mutect2, varscan2
- GLCCI1 | c.1015C>A p.R339= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as COSV56201798; called by muse, mutect2, varscan2
- GNA15 | c.525C>T p.Y175= | Silent (SNP) | VAF 48/139 reads (35%) | catalogued as rs372177672; called by muse, mutect2, varscan2
- HIVEP1 | c.564C>T p.S188= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as COSV65101408; called by muse, mutect2, varscan2
- LHX1 | c.891G>A p.P297= | Silent (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- NPTX1 | c.1263C>A p.T421= | Silent (SNP) | VAF 42/64 reads (66%) | catalogued as COSV60774973; called by muse, mutect2, varscan2
- OIT3 | c.1440C>T p.V480= | Silent (SNP) | VAF 69/213 reads (32%) | catalogued as COSV61826095; called by muse, mutect2, varscan2
- OR2T34 | c.726C>G p.A242= | Silent (SNP) | VAF 25/202 reads (12%) | catalogued as COSV60900437, COSV60901142; called by muse, mutect2, varscan2
- POLR3C | c.792C>T p.S264= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs782078317, COSV61936567; called by muse, mutect2, varscan2
- RSPO2 | c.360T>C p.H120= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as rs113070894, COSV52644265; called by muse, mutect2, varscan2
- SCAF11 | c.3630G>A p.P1210= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as rs773339022, COSV65476585; called by muse, mutect2, varscan2
- SI | c.5481A>T p.S1827= | Silent (SNP) | VAF 31/176 reads (18%) | catalogued as COSV52278493; called by muse, mutect2, varscan2
- STXBP5 | c.2046C>T p.P682= | Silent (SNP) | VAF 33/62 reads (53%) | catalogued as COSV51652088; called by muse, mutect2, varscan2
- TECPR1 | c.1575G>C p.P525= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV65783428; called by muse, mutect2, varscan2
- TTN | c.93498C>T p.D31166= (on ENST00000591111; = p.D23742= on NM_003319.4) | Silent (SNP) | VAF 40/99 reads (40%) | catalogued as COSV60060326; called by muse, mutect2, varscan2
- WDR1 | c.1479C>T p.T493= (on ENST00000382452; = p.T353= on NM_005112.5) | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs1423071266, COSV66724194; called by muse, mutect2, varscan2
- YBX2 | c.855C>T p.F285= | Silent (SNP) | VAF 65/99 reads (66%) | catalogued as COSV50300942; called by muse, mutect2, varscan2
- ACP4 | chr19:50798229 C>T | 3'Flank (SNP) | VAF 24/169 reads (14%) | catalogued as COSV54516887; called by muse, mutect2, varscan2
- AK9 | c.3633+13del | Intron (DEL) | VAF 6/40 reads (15%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- BSG | chr19:571550 G>A | 5'Flank (SNP) | VAF 21/81 reads (26%) | catalogued as COSV61076974; called by muse, mutect2, varscan2
- DCAF6 | c.1379-15366G>C | Intron (SNP) | VAF 8/43 reads (19%) | catalogued as COSV56578700; called by muse, mutect2, varscan2
- TTN | c.34265-5090A>C | Intron (SNP) | VAF 35/174 reads (20%) | catalogued as COSV60060369; called by muse, mutect2, varscan2
